Somatic mutation profile of tumor specimen TCGA-FG-A711-01A (aliquot TCGA-FG-A711-01A-21D-A33T-08) from TCGA case TCGA-FG-A711, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 33.5 years (12,248 days).
Specimen TCGA-FG-A711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70af86a2-7685-45c3-8d30-76b4c05cda33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A711-10A (Blood Derived Normal), aliquot TCGA-FG-A711-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c605a6a-2478-4746-ab50-4c27743ffea6

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 23, Silent 9, Splice Site 2, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 57/185 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 44/55 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV99568612; called by muse, mutect2, varscan2
- ANO3 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99885192; called by muse, mutect2, varscan2
- ARSL | c.1304A>G p.Q435R | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101140743; called by muse, mutect2, varscan2
- ATG4B | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100728769; called by muse, mutect2
- CASS4 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100824881, COSV99052672; called by muse, mutect2
- CDCP1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs374678265; called by muse, mutect2, varscan2
- CEP250 | c.3172A>G p.T1058A | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100699140; called by muse, mutect2, varscan2
- CERS6 | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99987618; called by muse, mutect2, varscan2
- CHD1 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV99399807; called by muse, mutect2, varscan2
- COL14A1 | c.4844T>A p.M1615K | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99920425; called by muse, mutect2, varscan2
- GRID1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs1405948467, COSV100026112; called by muse, mutect2, varscan2
- GSTA2 | c.417C>A p.V139= | Splice Region (SNP) | VAF 92/230 reads (40%) | catalogued as COSV101534071; called by muse, mutect2, varscan2
- ITIH2 | c.1787+1G>A p.X596_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100623388; called by muse, mutect2, varscan2
- KIAA0319 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100985767; called by muse, mutect2, varscan2
- L1CAM | c.3671C>T p.S1224L | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981159, COSV99055184; called by muse, mutect2, varscan2
- NIBAN2 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772145640, COSV55941898; called by muse, mutect2
- NT5DC1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs1486731692, COSV100127177, COSV60307664; called by muse, mutect2, varscan2
- ODC1 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 123/228 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52171956, COSV99301372; called by muse, mutect2, varscan2
- PCSK2 | c.1202+2T>A p.X401_splice | Splice Site (SNP) | VAF 16/213 reads (8%) | catalogued as COSV52741841, COSV99360523; called by muse, mutect2
- PTCD2 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs1272268559, COSV100349073; called by muse, mutect2, varscan2
- SGO2 | c.3184A>G p.I1062V | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100764782; called by muse, mutect2, varscan2
- SLC25A5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1250375775, COSV100510445; called by muse, mutect2, varscan2
- TACR3 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100510872; called by muse, mutect2, varscan2
- TRPV1 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as rs202102886, COSV51514868; called by muse, mutect2, varscan2
- ZC3H7B | c.320A>T p.K107M | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV100687697; called by muse, mutect2, varscan2
- ATRX | c.3008_3011del p.I1003Kfs*29 | Frame Shift Del (DEL) | VAF 168/454 reads (37%) | called by mutect2, pindel, varscan2
- AHNAK | c.12549C>T p.D4183= | Silent (SNP) | VAF 227/678 reads (33%) | catalogued as COSV99949261; called by muse, mutect2, varscan2
- CAPRIN2 | c.351G>A p.A117= | Silent (SNP) | VAF 91/273 reads (33%) | catalogued as rs151080170; called by muse, mutect2, varscan2
- CLCNKB | c.624C>T p.G208= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100990452; called by muse, mutect2, varscan2
- DYNC1I2 | c.1380C>T p.C460= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99784266; called by muse, mutect2
- GALNT14 | c.804C>T p.R268= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs770652926, COSV100205447; called by muse, mutect2, varscan2
- KRTAP21-2 | c.99C>T p.Y33= | Silent (SNP) | VAF 77/100 reads (77%) | catalogued as rs757305697, COSV61684262, COSV61684736; called by muse, mutect2, varscan2
- RETREG3 | c.24C>T p.P8= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs747055234, COSV99258880; called by muse, mutect2, varscan2
- RRAGB | c.861T>C p.H287= (on ENST00000262850 / NM_016656.4; = p.H259= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV99469594; called by muse, mutect2, varscan2
- SLC9A4 | c.835T>C p.L279= | Silent (SNP) | VAF 70/169 reads (41%) | catalogued as COSV99763461; called by muse, mutect2, varscan2
